Gene-level copy-number profile of tumor specimen TCGA-77-A5G7-01B from TCGA case TCGA-77-A5G7, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 63.2 years (23,090 days).
Specimen TCGA-77-A5G7-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.0126fcbe-39a6-4b89-9fc3-0dae79cdacd2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-77-A5G7-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/df405ab6-9495-4604-88b7-20d0b9b4a5a2

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 15,199; copy number 3: 13,002; copy number 4: 23,960; copy number 5: 3,648; copy number 6: 2,538; copy number 7: 116; copy number 8: 44; copy number 9: 1,101; copy number 10: 128; copy number 11: 43; copy number 13: 3; copy number 16: 8; copy number 20: 18; copy number 28: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-77-A5G7-01B-11D-A27J-01): tumor purity 0.58, ploidy 1.87, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,311 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:160,485,030–162,370,475, 84 genes, copy number 10 (within-gene range 4–10) (broad region; genes not listed).
- chr2:101,397,359–102,533,972, 22 genes, copy number 10: RFX8, LINC01870, RPS6P3, PRCPP1, AC093894.1, AC093894.2, MAP4K4, LINC01127, IL1R2, AC007271.1, IL1R1, IL1R1-AS1, IL1RL2, FAM183DP, IL1RL1, IL18R1, SDR42E1P5, IL18RAP, MIR4772, AC007278.2, AC007278.1, SLC9A4.
- chr3:152,118,173–198,222,513, 805 genes, copy number 9 (broad region; genes not listed).
- chr4:51,843,000–72,808,192, 321 genes, copy number 9–11 (broad region; genes not listed).
- chr8:36,277,763–36,988,412, 13 genes, copy number 13–28: MTCYBP19, MTND6P19, MTND5P41, AP006245.1, RNU6-533P, AP006245.2, AC090809.1, RPL23P10, RNA5SP264, KCNU1, AC124076.1, TPT1P8, AC090453.1.
- chr8:38,263,130–38,853,028, 18 genes, copy number 20: PLPP5, NSD3, AC087362.2, AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1, RNF5P1, AC016813.1, TACC1, Y_RNA, AC067817.1, AC067817.2.
- chr16:24,256,335–24,827,632, 8 genes, copy number 10 (within-gene range 3–10): CACNG3, AC004125.1, RNU7-24P, AC008938.1, RBBP6, TNRC6A, LINC01567, AC008731.1.
- chr18:24,162,045–24,397,880, 1 gene, copy number 9 (within-gene range 4–9): OSBPL1A.
- chr18:24,321,686–24,708,542, 14 genes, copy number 9: MIR320C2, AC023983.1, AC023983.2, IMPACT, Y_RNA, AC007922.2, HRH4, AC007922.1, AC007922.4, AC007922.3, EIF4A3P1, LINC01915, RAC1P1, PPIAP57.
- chr18:43,115,747–43,499,836, 3 genes, copy number 9: AC100779.1, SYT4, AC022743.1.
- chr20:10,996,293–11,926,609, 14 genes, copy number 10: LINC02871, AL158042.1, AL049649.1, RPS11P1, AL109837.2, AL109837.3, AL109837.1, PGAM3P, AL161938.1, LINC00687, RN7SKP111, AL080274.1, BTBD3, AL035448.1.
- chr21:20,424,949–21,615,437, 8 genes, copy number 16: KRT18P2, RPS3AP1, AP001506.1, LINC00320, PPIAP1, NCAM2, AP001136.1, AP001117.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
